Somatic mutation profile of tumor specimen MP2PRT-PAVXHZ-TMP1-A (aliquot MP2PRT-PAVXHZ-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVXHZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,307 days).
Specimen MP2PRT-PAVXHZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 234d3238-6f63-4edd-b66c-f774a58a3cf3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVXHZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVXHZ-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81e5fb15-ea77-458b-bef7-d151a0eebad6

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 2, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRNL1 | c.1342C>T p.H448Y | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs781934022; called by muse, mutect2, varscan2
- AXIN1 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV51990834; called by muse, mutect2, varscan2
- MEGF6 | c.3692C>T p.T1231M | Missense Mutation (SNP) | VAF 84/401 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753892111, COSV53886788; called by muse, mutect2, varscan2
- RBM27 | c.1777C>T p.R593* | Nonsense Mutation (SNP) | VAF 89/291 reads (31%) | catalogued as rs377645930, COSV54588381; called by muse, mutect2, varscan2
- SEMA3D | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 68/332 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.75); catalogued as rs1047048299, COSV52394259, COSV99033645; called by muse, mutect2, varscan2
- TNFRSF19 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 97/195 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as rs372905269, COSV99947737; called by muse, mutect2, varscan2
- CAMK1D | c.389A>G p.D130G | Missense Mutation (SNP) | VAF 72/412 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEACAM6 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 44/283 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CHD5 | c.4105C>A p.Q1369K | Missense Mutation (SNP) | VAF 76/364 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ITGAV | c.2290G>T p.V764F | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.838); called by muse, mutect2
- RGSL1 | c.1994A>G p.E665G | Missense Mutation (SNP) | VAF 105/366 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.438); called by muse, mutect2
- SYCP1 | c.716T>C p.M239T | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2
- TJP1 | c.2791T>A p.Y931N | Missense Mutation (SNP) | VAF 74/383 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TUBGCP2 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 119/703 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FAM47C | c.669C>A p.R223= | Silent (SNP) | VAF 122/330 reads (37%) | called by muse, varscan2
- OR4M1 | c.360T>C p.Y120= | Silent (SNP) | VAF 100/639 reads (16%) | called by muse, mutect2, varscan2
- MYL3 | chr3:46833080 G>C | 3'Flank (SNP) | VAF 74/410 reads (18%) | called by muse, mutect2, varscan2
